Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5277, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5277-01A (Primary Tumor).

[page 1 of 2]
al Diagnosis:

Brain, left frontal mass, biopsy and excision: Grade 3 (of 4) fibrillary astrocytoma (WHO, grade III).

Immunohistochemical stains were performed on paraffin-embedded tissue using antibodies to MIB-1 and p53 protein. p53 protein stain is strongly and diffusely expressed in neoplastic cells. MIB-1 labeling index is high. The findings support the above diagnosis.

TCGA-DB-5277

Preliminary Frozen Section Consultation:

Brain, left front mass, biopsy: Diffuse glioma. Hold to process, type and grade.

Brain, left frontal tissue, excision: Diffuse glioma, suspicious for intermediate grade (grade III).

Holdover.

Gross Description:

Portion of left frontal brain lobe (aggregating 0.5 x 0.3 x 0.2 cm) and separately submitted tissue from left frontal

[page 2 of 2]
lobe (5.8 x 4.0 x 2.0 cm).

Block Summary:

Part A: Left frontal brain

1 LT FRONTAL MASS

2 LT FRONTAL MASS

1 B: LT.FRONTAL TISSUE

1 lt frontal mass

2 lt frontal mass

3 lt frontal mass

4 lt frontal mass

5 lt frontal mass

6 lt frontal mass

7 lt frontal mass

8 lt frontal mass

9 lt frontal mass

10 lt frontal mass

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file e1a7b8ca-c55a-49d9-bfea-4e9cfa3babdd (TCGA-DB-5277.5DD3F674-5FFA-45CE-98FD-DB55AC716F8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).